Somatic mutation profile of tumor specimen 0DJPCV from CCDI case PBBXJJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,296 days).
Specimen 0DJPCV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec6ddc17-f4ec-4da8-99e3-0e4f3be0ee88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d7b60ea-9105-4d93-8258-a3d2c77c10cb

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, 3'UTR 3, Nonsense Mutation 3, Intron 3, 5'UTR 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 253/279 reads (91%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APOC2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 318/753 reads (42%) | catalogued as CD910633; called by muse, mutect2, varscan2
- CRX | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 231/507 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs771028537, COSV55759633; called by muse, mutect2, varscan2
- DHX34 | c.2380C>G p.R794G | Missense Mutation (SNP) | VAF 306/671 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.094); catalogued as rs763042083; called by muse, mutect2, varscan2
- EGLN3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs749363666, COSV99164314; called by muse, mutect2, varscan2
- FCHO1 | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 306/620 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773887321; called by muse, mutect2, varscan2
- MITD1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 295/665 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753859939; called by muse, mutect2, varscan2
- MTTP | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 248/541 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762020647; called by muse, mutect2, varscan2
- MYT1L | c.3185A>G p.E1062G | Missense Mutation (SNP) | VAF 199/431 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV67701617; called by muse, mutect2, varscan2
- PBRM1 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 52/198 reads (26%) | catalogued as COSV56260075; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by mutect2, varscan2
- TLR5 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 285/641 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs200696063, COSV60558441; called by muse, mutect2, varscan2
- ZFP42 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 291/682 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV58818502; called by muse, mutect2, varscan2
- ABCC8 | c.3727G>T p.A1243S | Missense Mutation (SNP) | VAF 428/941 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ANKRD20A1 | c.1841C>A p.A614D | Missense Mutation (SNP) | VAF 188/843 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 56/1252 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC62 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 178/458 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CDK12 | c.2188_2190del p.I730del | In Frame Del (DEL) | VAF 46/312 reads (15%) | called by pindel, varscan2
- CDK12 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNOT6 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 183/472 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DHTKD1 | c.2214C>A p.H738Q | Missense Mutation (SNP) | VAF 210/481 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- FAHD1 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 22/401 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2
- FMR1 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 197/511 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FRMD7 | c.557T>A p.M186K | Missense Mutation (SNP) | VAF 308/648 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GAS6 | c.1396A>T p.T466S | Missense Mutation (SNP) | VAF 129/725 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 61/2033 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IQSEC2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 174/327 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIR2DL1 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- LTA | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 307/728 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OTULIN | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 300/702 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PHF6 | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 407/969 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PHKA1 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 296/740 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RAB27B | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 358/754 reads (47%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD15 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 345/777 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TNIK | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 378/1302 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- VAPB | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 432/1022 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZAN | c.3526G>T p.G1176C | Missense Mutation (SNP) | VAF 326/752 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADTRP | c.522C>T p.Y174= | Silent (SNP) | VAF 321/805 reads (40%) | called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/428 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- DCAF4L2 | c.345C>T p.Y115= | Silent (SNP) | VAF 282/609 reads (46%) | catalogued as COSV60478313; called by muse, mutect2, varscan2
- DNAH14 | c.10416C>T p.T3472= (on ENST00000445597; = p.T4480= on NM_001367479.1) | Silent (SNP) | VAF 285/657 reads (43%) | catalogued as rs1160160466, COSV55288354; called by muse, mutect2, varscan2
- ERVV-2 | c.1431C>T p.F477= | Silent (SNP) | VAF 163/339 reads (48%) | catalogued as rs894146788; called by muse, mutect2, varscan2
- GPR61 | c.105G>A p.G35= | Silent (SNP) | VAF 318/671 reads (47%) | called by muse, mutect2, varscan2
- HMCN2 | c.7359T>C p.S2453= | Silent (SNP) | VAF 318/701 reads (45%) | called by muse, mutect2, varscan2
- MUC6 | c.4851A>C p.P1617= | Silent (SNP) | VAF 102/865 reads (12%) | catalogued as rs1421004819; called by muse, varscan2
- NEUROG1 | c.54C>T p.S18= | Silent (SNP) | VAF 311/709 reads (44%) | catalogued as rs955371579; called by muse, mutect2, varscan2
- SIGLEC8 | c.1158C>T p.S386= | Silent (SNP) | VAF 102/273 reads (37%) | catalogued as rs747635919; called by muse, mutect2, varscan2
- ZNF467 | c.1176C>T p.G392= | Silent (SNP) | VAF 210/414 reads (51%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- GP6 | c.-17G>T | 5'UTR (SNP) | VAF 163/378 reads (43%) | called by muse, mutect2, varscan2
- MFSD12 | c.1421-22C>T | Intron (SNP) | VAF 155/309 reads (50%) | catalogued as rs771454434; called by muse, mutect2, varscan2
- MYL3 | chr3:46833741 G>A | 3'Flank (SNP) | VAF 82/87 reads (94%) | catalogued as rs1338260701, COSV70133556; called by muse, mutect2, varscan2
- PORCN | c.*28C>A | 3'UTR (SNP) | VAF 155/259 reads (60%) | called by muse, mutect2, varscan2
- PTCH1 | c.3449+89A>G | Intron (SNP) | VAF 14/304 reads (5%) | catalogued as COSV100109080; called by muse, mutect2
- RBBP7 | c.-84A>C | 5'UTR (SNP) | VAF 113/245 reads (46%) | called by muse, mutect2, varscan2
- SVOPL | c.346-81G>A | Intron (SNP) | VAF 76/172 reads (44%) | catalogued as rs919584114, COSV55989993; called by muse, mutect2, varscan2
- TIPRL | c.*12A>G | 3'UTR (SNP) | VAF 148/381 reads (39%) | called by muse, mutect2, varscan2
